Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4T9, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4T9-01A (Primary Tumor).

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 B1 C1 D1 E1 F1 G1 H1 H2 H3 H4 H5 H6 H7 H8
Left upper lobe lung (175 grams), left upper lobe lung major fissure lymph node, stations 5L, 7L, 9L and 10L lymph nodes and left lower lobe bronchus lymph node

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Invasive grade 3 (of 4) adenocarcinoma forming a 3.0 x 2.0 x 1.4 cm subpleural mass situated 2.5 cm from the bronchial resection margin. The tumor involves the overlying visceral pleura with tumor present on the pleural surface. The bronchial resection margin is negative for tumor.

Lymph node, mediastinal, excision:

- Metastatic invasive grade 3 (of 4) adenocarcinoma is identified in two (of 2) left subaortic (station 5L) lymph node. Extranodal extension is also identified.
- No tumor is identified in multiple (3) left subcarinal (station 7L) lymph nodes.
- No tumor is identified in one (of 1) left pulmonary ligament (station 9L) lymph nodes.

Lymph node, intrapulmonary/hilar, excision:

- Metastatic invasive grade 3 (of 4) adenocarcinoma is identified in three (of 10) intraparenchymal peribronchial (IPPB) lymph nodes.
- No tumor is identified in one (of 1) left upper lung major fissure lymph node.
- No tumor is identified in two (of 2) left hilar (station 10L) lymph nodes.
- No tumor is identified in two (of 2) left lower lobe bronchus lymph nodes.

ICD-O-3

adenocarcinoma, NOS 8140/3
Site: lung, upper lobe C34.1

hw
10/29/12

Source: NCI Genomic Data Commons file 2f2fb3b9-cdf0-4376-a38c-381b51d73e9d (TCGA-MP-A4T9.FE06303C-736B-43C5-B692-FECA9A173EF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).